Gene-level copy-number profile of tumor specimen TCGA-LN-A49O-01A from TCGA case TCGA-LN-A49O, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 47.2 years (17,237 days).
Specimen TCGA-LN-A49O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.036ae2ad-059b-46e4-b1a5-e21ab6431212.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a111ea4-160d-4afa-93dd-e4b0c0276fdc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 111; copy number 2: 18,414; copy number 3: 24,910; copy number 4: 9,614; copy number 5: 2,370; copy number 6: 3,049; copy number 7: 662; copy number 8: 526; copy number 9: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49O-01A-11D-A246-01): tumor purity 0.58, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 133 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,652,374–185,800,151, 1 gene (within-gene range 0–3): FSIP2-AS1.
- chr2:185,719,874–186,509,361, 11 genes: FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr2:201,288,271–201,480,846, 5 genes (within-gene range 0–3): FLACC1, TRAK2, STRADB, SCYL2P1, Y_RNA.
- chr3:4,269,153–4,847,840, 5 genes (within-gene range 0–2): AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1.
- chr5:168,768,146–168,791,610, 2 genes: MIR218-2, Y_RNA.
- chr9:20,786,927–20,787,055, 1 gene: SNORA30B.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:87,751,512–87,863,533, 4 genes: ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr17:72,627,231–72,644,490, 2 genes: RPL32P33, AC080037.2.
- chr17:72,663,823–72,664,152, 1 gene: RN7SKP180.
- chr22:15,290,718–17,558,149, 93 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,211 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:82,754,012–114,075,920, 554 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:114,297,114–114,297,429, 1 gene, copy number 7: AC073626.2.
- chr12:66,767–23,251,499, 632 genes, copy number 7–8 (broad region; genes not listed).
- chr12:23,637,973–23,638,487, 1 gene, copy number 7: AC087260.1.
- chr14:67,386,984–67,816,590, 23 genes, copy number 9: PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
